Gene-level copy-number profile of tumor specimen HCM-BROD-0415-C71-02B from HCMI case HCM-BROD-0415-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.3 years (19,455 days).
Specimen HCM-BROD-0415-C71-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 81c69527-6664-4806-b8b0-73af065dfdec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0415-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/791f2b19-2c52-4c2d-9ad1-86212a0dff2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 4,734; copy number 2: 46,970; copy number 3: 6,606; copy number 4: 13; copy number 7: 2; copy number 29: 2; copy number 36: 2; copy number 38: 1; copy number 39: 1; copy number 41: 3; copy number 42: 3.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,128,103, 64 genes (broad region; genes not listed).
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,752,250–55,211,628, 5 genes, copy number 7–42: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr15:88,797,413–88,961,046, 6 genes, copy number 29–39: AC103982.1, ACAN, HAPLN3, MFGE8, AC067805.1, KRT18P47.
- chr15:89,037,977–89,088,377, 3 genes, copy number 41 (within-gene range 2–41): AC013565.2, AC013565.1, AC013565.3.

Autosomal genes at a single copy (total copy number 1): 4,716. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
